Somatic mutation profile of tumor specimen 0DXFDH from CCDI case PBCRFR, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Liver; Age at diagnosis: 17.9 years (6,530 days).
Specimen 0DXFDH: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2a3fad8e-2296-4a7f-be8d-3884bda8e7a7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DXFCR (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a3e9686f-0fcf-417b-9a91-594806d68b8d

The open-access MAF lists 62 somatic variants for this specimen: 35 protein-altering or splice-affecting, 12 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 12, 5'UTR 6, Intron 5, 3'UTR 2, Nonsense Mutation 1, RNA 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.134C>T p.S45F | Missense Mutation (SNP) | VAF 184/732 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs121913409, COSV62687872, COSV62688307, COSV62689938, COSV62711475; ClinVar: other / pathogenic / likely pathogenic; called by muse, varscan2
- ADCY7 | c.814G>A p.V272I | Missense Mutation (SNP) | VAF 176/630 reads (28%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.927); catalogued as rs199730202; called by muse, varscan2
- AMER3 | c.1010G>A p.R337K | Missense Mutation (SNP) | VAF 108/345 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.085); catalogued as COSV58466390; called by muse, mutect2, varscan2
- CUL2 | c.2014G>A p.V672I | Missense Mutation (SNP) | VAF 173/937 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as rs778685967; called by muse, mutect2, varscan2
- DGKK | c.3204G>C p.E1068D | Missense Mutation (SNP) | VAF 241/762 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101052984, COSV65707457; called by muse, mutect2, varscan2
- FRY | c.7091G>A p.R2364Q | Missense Mutation (SNP) | VAF 183/459 reads (40%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.552); catalogued as rs372186855, COSV66565174; called by muse, mutect2, varscan2
- LRRC43 | c.538G>A p.G180S | Missense Mutation (SNP) | VAF 129/584 reads (22%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as rs779702868, COSV60290337; called by muse, mutect2, varscan2
- MLXIP | c.1480C>A p.H494N | Missense Mutation (SNP) | VAF 201/964 reads (21%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.724); catalogued as COSV59835200; called by muse, mutect2, varscan2
- NAT2 | c.520G>T p.E174* | Nonsense Mutation (SNP) | VAF 112/575 reads (19%) | catalogued as COSV54061995; called by mutect2, varscan2
- NETO1 | c.958C>A p.P320T | Missense Mutation (SNP) | VAF 128/629 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV55003390; called by muse, mutect2, varscan2
- PPFIA1 | c.2108G>A p.R703Q | Missense Mutation (SNP) | VAF 167/916 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.781); catalogued as rs748144424, COSV54132778; called by muse, mutect2, varscan2
- TGM1 | c.286G>A p.G96S | Missense Mutation (SNP) | VAF 170/856 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0.018); catalogued as rs547714904; called by muse, mutect2, varscan2
- UBAC1 | c.592C>T p.R198W | Missense Mutation (SNP) | VAF 100/410 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as rs754962440; called by muse, varscan2
- ZDHHC6 | c.1221G>C p.E407D | Missense Mutation (SNP) | VAF 166/802 reads (21%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV61132610; called by muse, mutect2, varscan2
- ABCA2 | c.1361T>C p.I454T (on ENST00000614293; = p.I424T on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 100/370 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- ARHGEF18 | c.400G>A p.D134N (on ENST00000359920 / NM_001130955.2; = p.D30N on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 108/453 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.611); called by muse, mutect2, varscan2
- CHRM3 | c.1469C>T p.A490V | Missense Mutation (SNP) | VAF 152/723 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CLCN4 | c.671A>G p.E224G | Missense Mutation (SNP) | VAF 203/744 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CLIP3 | c.790G>C p.E264Q | Missense Mutation (SNP) | VAF 220/558 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.143); called by muse, varscan2
- COL4A3 | c.2107G>T p.G703W | Missense Mutation (SNP) | VAF 151/803 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DCBLD1 | c.38G>T p.R13L | Missense Mutation (SNP) | VAF 102/326 reads (31%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- EPS8L2 | c.1763A>T p.Q588L | Missense Mutation (SNP) | VAF 61/264 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- FAM122B | c.616G>T p.G206C (on ENST00000370790 / NM_001166599.3; = p.G207C on NM_145284.5) | Missense Mutation (SNP) | VAF 134/561 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HUWE1 | c.9895A>T p.N3299Y | Missense Mutation (SNP) | VAF 179/557 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- LONRF2 | c.16G>C p.V6L | Missense Mutation (SNP) | VAF 116/576 reads (20%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0.011); called by muse, mutect2
- NARF | c.680C>G p.P227R | Missense Mutation (SNP) | VAF 160/1020 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by mutect2, varscan2
- OR4K3 | c.166C>T p.H56Y | Missense Mutation (SNP) | VAF 121/1052 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- PMEL | c.846G>C p.E282D | Missense Mutation (SNP) | VAF 88/550 reads (16%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.766); called by mutect2, varscan2
- PPP1R13B | c.1132C>G p.H378D | Missense Mutation (SNP) | VAF 154/567 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.684); called by muse, mutect2, varscan2
- PPP1R27 | c.59T>C p.M20T | Missense Mutation (SNP) | VAF 175/1192 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- STK38L | c.1167G>T p.E389D | Missense Mutation (SNP) | VAF 120/550 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TACC2 | c.4181C>A p.T1394K | Missense Mutation (SNP) | VAF 71/389 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- WDR97 | c.2666A>G p.Q889R | Missense Mutation (SNP) | VAF 160/804 reads (20%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF236 | c.1882G>T p.D628Y | Missense Mutation (SNP) | VAF 66/352 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- ZNF526 | c.509A>G p.E170G | Missense Mutation (SNP) | VAF 115/539 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- ADGRG3 | c.222C>T p.Y74= | Silent (SNP) | VAF 137/494 reads (28%) | catalogued as rs762804141; called by muse, mutect2, varscan2
- AGTPBP1 | c.39C>T p.T13= | Silent (SNP) | VAF 92/464 reads (20%) | catalogued as COSV100429449; called by muse, mutect2, varscan2
- ELOA3D | c.855G>C p.L285= | Silent (SNP) | VAF 30/878 reads (3%) | called by muse, mutect2
- IL4I1 | c.10T>C p.L4= | Silent (SNP) | VAF 107/441 reads (24%) | called by muse, mutect2, varscan2
- IMMT | c.1812T>C p.S604= | Silent (SNP) | VAF 165/720 reads (23%) | catalogued as COSV54482348; called by muse, mutect2, varscan2
- MT1E | c.45C>T p.C15= | Silent (SNP) | VAF 259/1116 reads (23%) | catalogued as rs948970861, COSV100042260; called by muse, mutect2, varscan2
- OBSL1 | c.2940T>G p.T980= | Silent (SNP) | VAF 98/536 reads (18%) | called by muse, mutect2, varscan2
- PCDHB15 | c.2232C>G p.T744= | Silent (SNP) | VAF 129/654 reads (20%) | catalogued as rs1554292337, COSV51116142; called by muse, mutect2, varscan2
- PLAAT1 | c.15G>T p.S5= | Silent (SNP) | VAF 70/311 reads (23%) | catalogued as rs1216550404; called by muse, mutect2, varscan2
- RASA2 | c.2037G>C p.T679= | Silent (SNP) | VAF 228/1114 reads (20%) | called by muse, varscan2
- RORB | c.1354C>T p.L452= (on ENST00000396204 / NM_001365023.1; = p.L441= on NM_006914.4) | Silent (SNP) | VAF 215/874 reads (25%) | called by muse, mutect2, varscan2
- SMYD5 | c.327G>A p.Q109= | Silent (SNP) | VAF 217/926 reads (23%) | called by muse, mutect2, varscan2
- ALDH1A3 | c.667-53C>G | Intron (SNP) | VAF 22/82 reads (27%) | catalogued as COSV100320790; called by muse, varscan2
- ANKMY1 | c.-32T>A | 5'UTR (SNP) | VAF 162/694 reads (23%) | called by muse, mutect2, varscan2
- ARHGAP22 | c.323-13706G>T | Intron (SNP) | VAF 181/905 reads (20%) | called by muse, mutect2, varscan2
- COG7 | c.-75G>A | 5'UTR (SNP) | VAF 65/213 reads (31%) | called by muse, mutect2, varscan2
- EIF4E3 | c.-34C>A | 5'UTR (SNP) | VAF 8/34 reads (24%) | called by muse, mutect2
- KCNJ12 | c.-2G>A | 5'UTR (SNP) | VAF 58/382 reads (15%) | called by muse, mutect2
- LAMA4 | c.2056+34T>C | Intron (SNP) | VAF 67/246 reads (27%) | called by muse, mutect2, varscan2
- MUC19 | n.19414A>T | RNA (SNP) | VAF 126/637 reads (20%) | called by muse, mutect2, varscan2
- NAE1 | c.*24G>C | 3'UTR (SNP) | VAF 86/362 reads (24%) | called by muse, mutect2, varscan2
- PAGE5 | c.*44C>G | 3'UTR (SNP) | VAF 69/280 reads (25%) | called by muse, mutect2, varscan2
- PARP10 | c.1778-56C>A | Intron (SNP) | VAF 40/203 reads (20%) | called by muse, mutect2, varscan2
- PLA2G4C | c.-10G>A | 5'UTR (SNP) | VAF 170/648 reads (26%) | catalogued as rs367872447, COSV62784762; called by muse, mutect2, varscan2
- PRR12 | chr19:49594969 G>A | 5'Flank (SNP) | VAF 90/316 reads (28%) | catalogued as rs761475295, COSV55871005; called by muse, mutect2, varscan2
- SYT8 | c.31-47C>G | Intron (SNP) | VAF 44/104 reads (42%) | called by muse, mutect2, varscan2
- TSLP | c.-45G>A | 5'UTR (SNP) | VAF 78/286 reads (27%) | called by muse, mutect2, varscan2
